TCGA case TCGA-CM-6169 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e87ddca-f43e-4c6f-9d5b-430b666a7f6c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 67.3 years (24,564 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 396 days (1.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 19; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 89 days; Days to treatment end: 243 days; Number of cycles: 12; Treatment dose: 31,200 mg; Prescribed dose: 2600; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 89 days; Days to treatment end: 243 days; Number of cycles: 12; Treatment dose: 10,200 mg; Prescribed dose: 850; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 89 days; Days to treatment end: 243 days; Number of cycles: 12; Treatment dose: 7,050 mg; Prescribed dose: 850; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 89 days; Days to treatment end: 159 days; Number of cycles: 6; Treatment dose: 1,080 mg; Prescribed dose: 180; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 243 days; Disease response: Tumor Free.
- Days to follow up: 396 days (1.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 4.6 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 109.3 kg; Height: 176 cm; BMI: 35.3.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CM-6169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-CM-6169-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
  Slide TCGA-CM-6169-01A-01-TS1: Section location: Top; Percent tumor cells: 68; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 12; Percent stromal cells: 20.
- Sample TCGA-CM-6169-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CM-6169-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 4.6; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 396 days; disease-specific survival: no event (censored), 396 days; progression-free interval: no event (censored), 396 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CM-6169-01A-11D-1649-01): tumor purity 0.68, ploidy 2.11, whole-genome doublings 0.
